Somatic mutation profile of tumor specimen TCGA-ED-A459-01A (aliquot TCGA-ED-A459-01A-11D-A25V-10) from TCGA case TCGA-ED-A459, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 47.6 years (17,402 days).
Specimen TCGA-ED-A459-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdd1243c-1d6d-4c99-9291-b1256f0467e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A459-10A (Blood Derived Normal), aliquot TCGA-ED-A459-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9f6dd7a-0216-40b8-b277-b7abcf2daa96

The open-access MAF lists 274 somatic variants for this specimen: 201 protein-altering or splice-affecting, 55 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 55, Nonsense Mutation 14, 3'UTR 7, Intron 7, Splice Site 5, Frame Shift Del 4, RNA 2, In Frame Del 2, Splice Region 2, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 68/140 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM15 | c.1595A>T p.Q532L | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as COSV55128964; called by muse, mutect2
- ADAMTS12 | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 73/202 reads (36%) | catalogued as COSV61272818; called by muse, mutect2, varscan2
- AK8 | c.227G>A p.W76* | Nonsense Mutation (SNP) | VAF 16/116 reads (14%) | catalogued as COSV53758375; called by muse, mutect2, varscan2
- AKR7L | c.505-2A>T p.X169_splice | Splice Site (SNP) | VAF 20/166 reads (12%) | catalogued as COSV70167784; called by mutect2, varscan2
- ALDH16A1 | c.2226G>T p.M742I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV53195757; called by muse, mutect2, varscan2
- ALG9 | c.1643A>T p.E548V (on ENST00000614444 / NM_001352418.1; = p.E555V on NM_024740.2) | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV67645227; called by muse, mutect2
- ALK | c.4432A>G p.M1478V | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV66582918; called by muse, mutect2, varscan2
- ALPK1 | c.2683A>G p.N895D | Missense Mutation (SNP) | VAF 70/135 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV51589517; called by muse, mutect2, varscan2
- AMZ1 | c.142T>A p.Y48N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56688457; called by muse, mutect2, varscan2
- ANKRD30A | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1391060906, COSV100652584; called by muse, mutect2, varscan2
- ANKRD52 | c.3191G>T p.R1064L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.303); catalogued as COSV57286331; called by muse, mutect2, varscan2
- ANXA7 | c.683A>T p.K228M (on ENST00000372919 / NM_001320880.2; = p.K206M on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65824124; called by muse, mutect2, varscan2
- AP4E1 | c.2246A>T p.D749V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV55919023; called by muse, mutect2
- ARHGEF2 | c.1271A>T p.E424V (on ENST00000361247 / NM_001162383.2; = p.E396V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58114854; called by muse, mutect2, varscan2
- ASPM | c.1935C>A p.F645L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV54135327; called by muse, mutect2, varscan2
- ATP10B | c.1182A>T p.Q394H | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58780209; called by muse, mutect2
- BCAS3 | c.2372+1G>A p.X791_splice (on ENST00000390652 / NM_001353144.2; = p.X776_splice on NM_017679.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 43/145 reads (30%) | catalogued as COSV66770671; called by muse, mutect2, varscan2
- BPTF | c.6092A>G p.E2031G | Missense Mutation (SNP) | VAF 96/267 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58843472; called by muse, mutect2, varscan2
- BRPF1 | c.200A>C p.Q67P | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV57406855; called by muse, mutect2, varscan2
- BTBD7 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as rs1198567556, COSV100597941, COSV58283311; called by muse, mutect2, varscan2
- BTN2A2 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 130/400 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61858154; called by muse, mutect2
- CA6 | c.639C>A p.Y213* | Nonsense Mutation (SNP) | VAF 231/822 reads (28%) | catalogued as COSV66262653; called by muse, mutect2, varscan2
- CACNA1G | c.2588A>G p.D863G | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61734108; called by muse, mutect2
- CAND2 | c.1060G>T p.A354S (on ENST00000456430 / NM_001162499.2; = p.A261S on NM_012298.3) | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as COSV55992680, COSV55992859; called by muse, mutect2, varscan2
- CEP126 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV54828887; called by muse, mutect2, varscan2
- CEP170 | c.1079A>T p.D360V | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449160283, COSV60512351; called by muse, mutect2
- CLCN7 | c.469A>T p.R157W | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV51972618; called by muse, mutect2
- COPS3 | c.161A>T p.H54L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52006769; called by muse, varscan2
- CPNE4 | c.427A>T p.I143F | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV70198066; called by muse, mutect2
- CR1 | c.204T>A p.Y68* | Nonsense Mutation (SNP) | VAF 35/442 reads (8%) | catalogued as COSV65461390; called by muse, mutect2
- CRAT | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.8); catalogued as COSV58878433; called by muse, mutect2, varscan2
- CUBN | c.3660A>T p.L1220F | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV64719371, COSV64723157; called by muse, mutect2
- DENND5A | c.2288A>C p.K763T | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60236617; called by muse, mutect2
- DIXDC1 | c.1313A>T p.Q438L (on ENST00000440460 / NM_001037954.4; = p.Q227L on NM_033425.4) | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV59462921; called by muse, mutect2
- DNAJC5 | c.473A>T p.Q158L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV62672879; called by muse, mutect2
- DNER | c.1113A>T p.Q371H | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV59172620; called by muse, mutect2
- DNM2 | c.1134G>C p.E378D | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.033); catalogued as rs1223342362, COSV58967014, COSV58968648; called by muse, mutect2, varscan2
- DNMT1 | c.3368A>C p.Q1123P | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61582085; called by muse, mutect2, varscan2
- DPYSL3 | c.548A>T p.E183V | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV58329646; called by muse, mutect2
- DSCAM | c.6016G>C p.A2006P | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as COSV68028967; called by muse, mutect2, varscan2
- EIF3D | c.410A>T p.Q137L | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.439); catalogued as COSV53404661; called by muse, mutect2
- ERICH6 | c.922A>T p.I308F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV55802268; called by muse, mutect2
- F5 | c.1277A>T p.Q426L | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63126471; called by muse, mutect2
- FAU | c.394A>T p.N132Y | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54195620; called by muse, mutect2
- FIS1 | c.206A>T p.E69V | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV56191869, COSV56192209; called by muse, mutect2
- FRRS1 | c.1781A>T p.Q594L | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54923591; called by muse, mutect2, varscan2
- GAD2 | c.1565G>A p.R522K | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs377565192; called by muse, mutect2, varscan2
- GLE1 | c.1085A>G p.E362G | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV59409468; called by muse, mutect2, varscan2
- GORAB | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); catalogued as rs777973388, COSV63028595; called by muse, mutect2
- GPR153 | c.469T>G p.Y157D | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64938829; called by muse, mutect2, varscan2
- GPR176 | c.586T>A p.W196R | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV54447268; called by muse, mutect2
- GRIK2 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59757959; called by muse, mutect2, varscan2
- HNRNPH2 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 181/243 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57266991; called by muse, mutect2, varscan2
- HNRNPLL | c.874G>C p.G292R | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV55368769; called by muse, mutect2, varscan2
- HOXA6 | c.240T>A p.Y80* | Nonsense Mutation (SNP) | VAF 49/152 reads (32%) | catalogued as rs1319069268, COSV56074366; called by muse, mutect2, varscan2
- HUWE1 | c.386A>T p.Q129L | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV53358230; called by muse, mutect2
- ITFG2 | c.397A>T p.S133C | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.594); catalogued as COSV57390496; called by muse, mutect2, varscan2
- ITGB5 | c.152A>T p.K51I | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV56150890, COSV56151728; called by muse, mutect2
- ITIH5 | c.1083C>A p.Y361* | Nonsense Mutation (SNP) | VAF 71/371 reads (19%) | catalogued as COSV53661822, COSV53671325; called by muse, mutect2, varscan2
- KALRN | c.1364A>T p.H455L | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV53775085; called by muse, mutect2, varscan2
- KCNK6 | c.351T>A p.D117E | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV54580342; called by muse, mutect2
- KIF19 | c.2147G>T p.G716V | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as COSV63430246; called by muse, mutect2, varscan2
- KIF1B | c.3880A>T p.I1294F (on ENST00000377086 / NM_001365952.1; = p.I1248F on NM_015074.3) | Missense Mutation (SNP) | VAF 103/336 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV55813144; called by muse, mutect2, varscan2
- KITLG | c.715-2A>T p.X239_splice | Splice Site (SNP) | VAF 10/95 reads (11%) | catalogued as COSV57200594, COSV57203235; called by muse, mutect2
- KMT2C | c.6010A>T p.S2004C | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.315); catalogued as COSV51479818; called by muse, mutect2, varscan2
- LAMA1 | c.3290C>A p.T1097K | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV67534888, COSV67541584; called by muse, mutect2, varscan2
- LENG8 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.07); catalogued as COSV58729517; called by muse, mutect2
- LEPR | c.2053A>T p.T685S | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV60760635; called by muse, mutect2
- LGALS8 | c.767T>C p.I256T (on ENST00000341872; = p.I298T on NM_006499.4) | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1476943972, COSV53025827; called by muse, mutect2, varscan2
- LIFR | c.2134T>A p.L712I | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV54696511; called by muse, mutect2, varscan2
- LINGO1 | c.574A>C p.S192R | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.619); catalogued as COSV62438013; called by muse, mutect2, varscan2
- LMAN1L | c.1200-1G>T p.X400_splice | Splice Site (SNP) | VAF 7/44 reads (16%) | catalogued as rs752683861, COSV59002967; called by muse, mutect2, varscan2
- LRGUK | c.1507A>T p.R503* | Nonsense Mutation (SNP) | VAF 15/182 reads (8%) | catalogued as COSV53641545; called by muse, mutect2
- MAEA | c.965A>T p.N322I (on ENST00000303400 / NM_001017405.3; = p.N281I on NM_005882.5) | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV53264081; called by muse, mutect2
- MAN2A1 | c.73A>G p.M25V | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as rs769889577, COSV54856202; called by muse, mutect2, varscan2
- MAP4K4 | c.2150C>G p.S717C (on ENST00000347699 / NM_001242559.2; = p.S632C on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.922); catalogued as rs1179532178, COSV56337349; called by muse, mutect2, varscan2
- MATK | c.857A>T p.E286V (on ENST00000310132 / NM_139355.3; = p.E287V on NM_002378.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV59556051; called by muse, mutect2, varscan2
- MEI1 | c.236T>A p.L79Q | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as COSV55905725; called by muse, mutect2
- METTL15 | c.158A>C p.Q53P | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.019); catalogued as COSV57722274; called by muse, mutect2, varscan2
- MGLL | c.245A>G p.Q82R (on ENST00000398104 / NM_001003794.2; = p.Q92R on NM_007283.6) | Missense Mutation (SNP) | VAF 108/300 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as COSV54028386; called by muse, mutect2, varscan2
- MICAL1 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62195286; called by muse, mutect2
- MMP17 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749455826, COSV62178941; called by muse, mutect2, varscan2
- MRPS25 | c.500T>A p.L167Q | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV53741955; called by muse, mutect2
- MS4A2 | c.291A>T p.K97N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV54013441; called by muse, mutect2, varscan2
- MUCL3 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs960064176, COSV58518464; called by muse, mutect2, varscan2
- MYH7B | c.2647A>G p.K883E | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV53423480; called by muse, mutect2, varscan2
- MYH8 | c.922A>T p.T308S | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV67970048; called by muse, mutect2
- MYO3A | c.3556T>A p.Y1186N | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV56342582; called by muse, mutect2
- MYO7B | c.743A>T p.E248V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV67350128; called by muse, varscan2
- MYOF | c.3232A>T p.R1078* | Nonsense Mutation (SNP) | VAF 14/209 reads (7%) | catalogued as COSV63708419; called by muse, mutect2
- NCSTN | c.1433A>T p.N478I | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV54190353; called by muse, mutect2
- NELL2 | c.2234T>A p.I745N | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV61582037; called by muse, mutect2, varscan2
- NIP7 | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 66/123 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV54742119; called by muse, mutect2, varscan2
- NISCH | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.232); catalogued as COSV51768144; called by muse, mutect2, varscan2
- NKTR | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51774047; called by muse, mutect2, varscan2
- NLGN4X | c.238T>A p.S80T | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV52030157; called by muse, mutect2
- NPC1L1 | c.1226A>T p.Q409L | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV56928586; called by muse, mutect2
- NR2C1 | c.516A>T p.R172S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV58011609; called by muse, mutect2
- NXPH1 | c.257A>T p.D86V | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV68318171; called by muse, mutect2, varscan2
- OASL | c.1540A>T p.S514C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV56568083; called by muse, mutect2
- OASL | c.1538C>G p.A513G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV56568089; called by muse, mutect2
- OIT3 | c.458A>T p.E153V | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV61826914; called by muse, mutect2, varscan2
- OR5H14 | c.86T>A p.L29Q | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV71194345; called by muse, mutect2
- OR6Y1 | c.364A>T p.I122F | Missense Mutation (SNP) | VAF 38/411 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV56930743; called by muse, mutect2
- PCDHA2 | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as rs1554120396, COSV65369368; called by muse, varscan2
- PCDHGA5 | c.869A>T p.E290V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.296); catalogued as COSV54001704; called by muse, mutect2, varscan2
- PGP | c.878A>T p.Q293L | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV57030684; called by muse, mutect2
- PHF2 | c.569T>A p.L190H | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63682907; called by muse, mutect2
- PIK3R3 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV53110014; called by mutect2, varscan2
- PKD2L2 | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51800130; called by muse, mutect2, varscan2
- PLEKHG3 | c.1653G>T p.E551D (on ENST00000394691; = p.E607D on NM_001308147.2) | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55982354; called by muse, mutect2, varscan2
- PNMA5 | c.348T>A p.S116R | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62626041; called by muse, mutect2
- PPARGC1A | c.2330A>T p.K777M | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1274372187, COSV53523956, COSV53531730; called by muse, mutect2
- PRKAR2B | c.584A>T p.D195V | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55926905; called by muse, mutect2
- RALGAPA1 | c.2626A>G p.N876D | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV51892002; called by muse, mutect2, varscan2
- RASGRP1 | c.254T>A p.L85Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV60366861; called by muse, mutect2, varscan2
- RD3 | c.406C>A p.H136N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs1198032436, COSV65362668; called by muse, mutect2, varscan2
- RGL2 | c.839A>T p.H280L | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as COSV65842768; called by muse, mutect2
- RNF43 | c.1730A>T p.Q577L | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV68459409; called by muse, mutect2
- RP1 | c.4773G>A p.W1591* | Nonsense Mutation (SNP) | VAF 32/59 reads (54%) | catalogued as COSV55123166, COSV99606116; called by muse, mutect2, varscan2
- RUBCN | c.1040A>T p.E347V | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV56371249; called by muse, mutect2, varscan2
- SAGE1 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 110/1124 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.668); catalogued as COSV61016048; called by muse, mutect2
- SCN11A | c.1771A>T p.T591S | Missense Mutation (SNP) | VAF 111/331 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56575118; called by muse, mutect2, varscan2
- SCN1A | c.2209T>A p.C737S (on ENST00000303395 / NM_001202435.3; = p.C726S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV57681158; called by muse, mutect2, varscan2
- SCN2A | c.5588A>T p.K1863M | Missense Mutation (SNP) | VAF 87/347 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51850828; called by muse, mutect2, varscan2
- SCN9A | c.379T>G p.L127V | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV57619027; called by muse, mutect2, varscan2
- SFXN4 | c.667A>T p.K223* | Nonsense Mutation (SNP) | VAF 16/204 reads (8%) | catalogued as COSV57460709; called by muse, mutect2
- SHANK3 | c.958T>A p.F320I | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53189646; called by muse, mutect2
- SLC25A39 | c.622G>A p.A208T (on ENST00000377095 / NM_001143780.3; = p.A200T on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV56586943; called by muse, mutect2, varscan2
- SLC35B2 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.047); catalogued as COSV51491116; called by muse, mutect2, varscan2
- SLC6A15 | c.451T>C p.C151R | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57027294; called by muse, mutect2, varscan2
- SLC6A17 | c.28C>A p.R10S | Missense Mutation (SNP) | VAF 146/327 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV58994947; called by muse, mutect2, varscan2
- SLITRK5 | c.2770T>A p.F924I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100280020; called by muse, mutect2
- SMG5 | c.2173A>T p.S725C | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.799); catalogued as COSV62436882; called by muse, mutect2
- SPDL1 | c.932C>T p.T311I | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV54669144; called by muse, mutect2, varscan2
- SPEG | c.3458T>A p.V1153E | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV56676517; called by muse, mutect2, varscan2
- SPOCK1 | c.815T>A p.I272N | Missense Mutation (SNP) | VAF 125/362 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV56459808; called by muse, mutect2, varscan2
- SRD5A2 | c.545A>T p.Q182L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV51872983; called by muse, mutect2
- STAT3 | c.1919A>T p.Y640F | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); catalogued as rs769031989, COSV52882807; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- STRIP1 | c.985C>G p.R329G | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV63929978; called by muse, mutect2, varscan2
- SYNGAP1 | c.617T>C p.I206T | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV53385012; called by muse, mutect2, varscan2
- TAF1D | c.352T>C p.S118P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV58681605; called by muse, mutect2, varscan2
- TAF1L | c.5089A>G p.T1697A | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV54266362; called by muse, mutect2, varscan2
- TAS1R3 | c.1124G>T p.C375F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV59564825; called by muse, mutect2, varscan2
- TEX15 | c.2882A>T p.Q961L (on ENST00000256246; = p.Q1344L on NM_001350162.2) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV56350874; called by muse, mutect2, varscan2
- TFRC | c.1579A>T p.N527Y | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64055892; called by muse, mutect2
- TGM6 | c.1367A>T p.K456M | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV52482761; called by muse, mutect2
- TGM7 | c.1834A>G p.I612V | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs934035706, COSV71773012; called by muse, mutect2
- TIMP4 | c.572A>T p.Q191L | Missense Mutation (SNP) | VAF 34/472 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55139707; called by muse, mutect2
- TKTL1 | c.1759A>T p.I587L | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV54214161; called by muse, mutect2
- TMEM127 | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51498682; called by muse, mutect2, varscan2
- TNC | c.2224T>A p.W742R | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60788537; called by muse, mutect2, varscan2
- TNF | c.291A>T p.Q97H | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as COSV69305186; called by muse, mutect2
- TPH1 | c.158C>G p.S53* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV51459450; called by muse, mutect2, varscan2
- TPSD1 | c.601A>T p.T201S | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV52977763; called by muse, mutect2
- TRHR | c.152T>C p.M51T | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61235817; called by muse, mutect2, varscan2
- TRPA1 | c.1997C>A p.P666Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51569823, COSV51570394; called by muse, mutect2
- TRPM1 | c.2701A>T p.I901F | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.574); catalogued as COSV56639341; called by muse, mutect2
- TTN | c.72587C>T p.P24196L (on ENST00000591111; = p.P16772L on NM_003319.4) | Missense Mutation (SNP) | VAF 28/298 reads (9%) | PolyPhen benign (0.121); catalogued as rs752618930, COSV60207366, COSV60240510; ClinVar: uncertain significance; called by muse, mutect2
- UBR4 | c.6515A>T p.N2172I | Missense Mutation (SNP) | VAF 226/394 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64395850; called by muse, mutect2, varscan2
- UGT2B7 | c.311C>A p.T104K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV59444890; called by muse, mutect2, varscan2
- ULK1 | c.1095A>G p.P365= | Splice Region (SNP) | VAF 36/70 reads (51%) | catalogued as COSV58859022, COSV58860447; called by muse, mutect2, varscan2
- UNC80 | c.4835C>T p.A1612V | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV55900733; called by muse, mutect2, varscan2
- UPF1 | c.1756C>T p.Q586* (on ENST00000599848 / NM_001297549.2; = p.Q575* on NM_002911.4) | Nonsense Mutation (SNP) | VAF 8/128 reads (6%) | catalogued as COSV53199943; called by muse, mutect2
- USP8 | c.2122A>G p.R708G | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV56166934; called by muse, mutect2, varscan2
- YTHDC2 | c.1846A>T p.I616F | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV50748710; called by muse, mutect2
- ZEB2 | c.2768A>T p.Y923F | Missense Mutation (SNP) | VAF 88/286 reads (31%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.956); catalogued as COSV100355702, COSV57962683; called by muse, mutect2, varscan2
- ZGRF1 | c.5910+1G>T p.X1970_splice | Splice Site (SNP) | VAF 44/87 reads (51%) | catalogued as COSV71393595; called by muse, mutect2, varscan2
- ZIC4 | c.835A>T p.S279C | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67173362; called by muse, mutect2
- ZNF41 | c.1811A>G p.E604G | Missense Mutation (SNP) | VAF 185/216 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57444581; called by muse, mutect2, varscan2
- ZNF462 | c.6617T>A p.I2206N | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV52947290; called by muse, mutect2
- ZNF547 | c.895A>T p.S299C | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV56581493; called by muse, mutect2
- ZNF585B | c.1325A>T p.H442L | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV57216475; called by muse, mutect2
- ZNF613 | c.1760A>T p.N587I (on ENST00000293471 / NM_001031721.4; = p.N551I on NM_024840.4) | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV53273215; called by muse, mutect2, varscan2
- ZNF629 | c.2036A>T p.Q679L | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.378); catalogued as COSV52699905; called by muse, mutect2
- ZNF773 | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV56589789; called by muse, mutect2
- ZNF85 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs1169591328, COSV60216414; called by muse, mutect2, varscan2
- ZPBP | c.207A>T p.P69= | Splice Region (SNP) | VAF 10/100 reads (10%) | catalogued as COSV50430522; called by muse, mutect2
- AEBP1 | c.1375A>C p.T459P | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CFAP54 | c.5030T>C p.L1677S | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CNTNAP2 | c.2372G>T p.C791F | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNA2 | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 46/154 reads (30%) | called by muse, varscan2
- DSCAM | c.6017C>T p.A2006V | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FBXO42 | c.1174_1175del p.Q392Vfs*8 | Frame Shift Del (DEL) | VAF 23/216 reads (11%) | called by mutect2, pindel, varscan2
- GCOM1 | c.428A>T p.Q143L | Missense Mutation (SNP) | VAF 6/168 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2
- GPAT2 | c.2131G>T p.G711C | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- HIP1 | c.2327A>T p.Q776L | Missense Mutation (SNP) | VAF 11/280 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- IGKV1-12 | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 111/2300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- IGKV5-2 | c.63A>T p.E21D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.632); called by muse, mutect2
- IGSF9 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 44/560 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- IL6ST | c.642_650del p.F214_V217delinsL | In Frame Del (DEL) | VAF 28/106 reads (26%) | called by mutect2, pindel, varscan2
- ITGA7 | c.2579A>T p.Q860L (on ENST00000555728; = p.Q816L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2
- LPIN1 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- MROH2A | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.972); called by muse, mutect2
- NEFH | c.1661_1665del p.A554Gfs*8 | Frame Shift Del (DEL) | VAF 53/191 reads (28%) | called by mutect2, pindel, varscan2
- SAA1 | c.281_282insA p.L95Afs*3 | Frame Shift Ins (INS) | VAF 83/287 reads (29%) | called by mutect2, pindel, varscan2
- SUPT6H | c.3440_3441del p.E1147Gfs*35 | Frame Shift Del (DEL) | VAF 58/254 reads (23%) | called by pindel, varscan2
- TSKU | c.290_292del p.T97del | In Frame Del (DEL) | VAF 19/179 reads (11%) | called by mutect2, varscan2
- ZBED4 | c.774_798del p.P259Qfs*4 | Frame Shift Del (DEL) | VAF 42/147 reads (29%) | called by mutect2, varscan2
- ZGRF1 | c.5813C>T p.A1938V | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.348); called by muse, varscan2
- ALPK3 | c.3093G>T p.L1031= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV51937470; called by muse, mutect2, varscan2
- AURKA | c.48A>T p.T16= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV57169543; called by muse, mutect2
- B3GNT4 | c.879T>A p.A293= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV57337107; called by muse, mutect2, varscan2
- CCR7 | c.249T>C p.Y83= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as rs753052328, COSV55850161; called by muse, mutect2, varscan2
- CD38 | c.663T>G p.T221= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV56892082; called by muse, mutect2, varscan2
- CD6 | c.969C>G p.S323= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs150066453, COSV100533208, COSV57841241; called by muse, mutect2, varscan2
- CEP97 | c.600G>A p.L200= | Silent (SNP) | VAF 33/217 reads (15%) | catalogued as COSV59126664; called by muse, mutect2, varscan2
- CFAP65 | c.561C>T p.F187= | Silent (SNP) | VAF 50/181 reads (28%) | catalogued as COSV55390778; called by muse, mutect2, varscan2
- CHDH | c.627C>T p.A209= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs1198143434, COSV59459142; called by muse, mutect2
- CNTNAP2 | c.2373C>T p.C791= | Silent (SNP) | VAF 17/256 reads (7%) | called by muse, mutect2
- DDX46 | c.1026A>T p.L342= | Silent (SNP) | VAF 13/205 reads (6%) | catalogued as COSV62800424; called by muse, mutect2
- EIF3A | c.3303A>T p.R1101= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as rs901998364; called by muse, mutect2, varscan2
- F8 | c.3564A>T p.P1188= | Silent (SNP) | VAF 7/135 reads (5%) | catalogued as COSV64277040; called by muse, mutect2
- FN1 | c.3552A>G p.A1184= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV60559924; called by muse, mutect2, varscan2
- GET4 | c.207A>C p.G69= | Silent (SNP) | VAF 28/106 reads (26%) | called by muse, mutect2, varscan2
- IL10RA | c.1260G>T p.S420= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as COSV57141657; called by muse, mutect2, varscan2
- ITGA6 | c.1542A>T p.T514= (on ENST00000442250; = p.T475= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV51243424; called by muse, mutect2, varscan2
- KNSTRN | c.78A>T p.P26= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as COSV51108630; called by muse, mutect2
- KRT40 | c.1065G>A p.E355= | Silent (SNP) | VAF 45/140 reads (32%) | catalogued as COSV66696725; called by muse, mutect2, varscan2
- LRRK2 | c.279A>T p.P93= | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as COSV100108558; called by muse, mutect2
- MCF2L | c.1521G>A p.A507= (on ENST00000375608; = p.A475= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/190 reads (27%) | catalogued as rs141497667; called by muse, mutect2, varscan2
- MDN1 | c.13884T>C p.S4628= | Silent (SNP) | VAF 46/161 reads (29%) | catalogued as COSV65527223; called by muse, mutect2, varscan2
- MDN1 | c.13761G>T p.S4587= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV65527230; called by muse, mutect2, varscan2
- MMP12 | c.969C>T p.S323= | Silent (SNP) | VAF 39/174 reads (22%) | catalogued as COSV58259713; called by muse, mutect2, varscan2
- MROH7 | c.1254A>G p.S418= | Silent (SNP) | VAF 127/329 reads (39%) | catalogued as COSV59875775; called by muse, mutect2, varscan2
- MTMR11 | c.1017A>T p.S339= (on ENST00000439741 / NM_001145862.2; = p.S267= on NM_181873.3) | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as COSV54966420; called by muse, mutect2
- NADK | c.483C>T p.F161= | Silent (SNP) | VAF 62/154 reads (40%) | catalogued as rs747159807, COSV100411099, COSV58275217; called by muse, mutect2, varscan2
- NCKIPSD | c.1833A>T p.P611= | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as COSV53662763; called by muse, mutect2
- NCL | c.519A>T p.A173= | Silent (SNP) | VAF 18/215 reads (8%) | catalogued as COSV59547052; called by muse, mutect2
- NOL6 | c.2100A>T p.P700= | Silent (SNP) | VAF 68/159 reads (43%) | catalogued as COSV53044614; called by muse, mutect2, varscan2
- NTS | c.387T>A p.T129= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as COSV55456747; called by muse, mutect2
- PDSS1 | c.1009C>T p.L337= | Silent (SNP) | VAF 78/303 reads (26%) | catalogued as rs541206852, COSV66059821; called by muse, mutect2, varscan2
- PFKP | c.1470G>A p.E490= | Silent (SNP) | VAF 55/256 reads (21%) | catalogued as COSV66900489; called by muse, mutect2, varscan2
- PLCB3 | c.543A>T p.A181= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV54191066; called by muse, mutect2
- PRH1 | c.45A>T p.S15= | Silent (SNP) | VAF 16/220 reads (7%) | catalogued as COSV70372216; called by muse, mutect2
- RYR2 | c.9513G>A p.L3171= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as COSV63703653; called by muse, mutect2, varscan2
- SDR9C7 | c.337C>T p.L113= | Silent (SNP) | VAF 11/190 reads (6%) | catalogued as COSV53290206; called by muse, mutect2
- SI | c.363A>T p.T121= | Silent (SNP) | VAF 15/358 reads (4%) | catalogued as COSV100013277; called by muse, mutect2
- SLC26A7 | c.891T>A p.P297= | Silent (SNP) | VAF 13/216 reads (6%) | catalogued as COSV52600767; called by muse, mutect2
- SPDYC | c.373C>T p.L125= | Silent (SNP) | VAF 17/255 reads (7%) | catalogued as COSV65865533; called by muse, mutect2
- STAB2 | c.2409A>T p.I803= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as COSV66344046; called by muse, mutect2
- STXBP4 | c.318A>T p.I106= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV54843056; called by muse, mutect2
- TAF8 | c.675A>T p.T225= | Silent (SNP) | VAF 20/304 reads (7%) | catalogued as COSV65896781; called by muse, mutect2
- TDRD5 | c.357G>A p.R119= | Silent (SNP) | VAF 110/333 reads (33%) | catalogued as COSV54247935; called by muse, mutect2, varscan2
- TENM2 | c.1281T>C p.D427= | Silent (SNP) | VAF 124/432 reads (29%) | catalogued as COSV69137545; called by muse, varscan2
- TIMP4 | c.306T>C p.C102= | Silent (SNP) | VAF 48/160 reads (30%) | catalogued as rs771959850, COSV55139718; called by muse, mutect2, varscan2
- TSHZ3 | c.1854T>A p.T618= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as COSV53678418; called by muse, mutect2
- TUT4 | c.1959A>T p.V653= | Silent (SNP) | VAF 11/125 reads (9%) | catalogued as COSV57117984; called by muse, mutect2
- UBQLNL | c.102A>T p.I34= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV66492609, COSV66494156; called by muse, mutect2
- USH2A | c.9927A>G p.G3309= | Silent (SNP) | VAF 153/373 reads (41%) | catalogued as COSV56411057; called by muse, mutect2, varscan2
- VPS13D | c.636T>A p.T212= | Silent (SNP) | VAF 96/290 reads (33%) | catalogued as COSV62532890; called by muse, mutect2, varscan2
- VWA3A | c.693C>T p.L231= | Silent (SNP) | VAF 34/162 reads (21%) | catalogued as COSV67013580; called by muse, mutect2, varscan2
- VWCE | c.2370A>T p.S790= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV57114152; called by muse, mutect2
- ZNF211 | c.852T>G p.P284= (on ENST00000347302 / NM_198855.4; = p.P297= on NM_006385.5) | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV53744307; called by muse, mutect2, varscan2
- ZNF326 | c.369A>T p.G123= | Silent (SNP) | VAF 18/227 reads (8%) | catalogued as COSV61035996; called by muse, mutect2
- ADARB2 | c.101-147692T>A | Intron (SNP) | VAF 7/105 reads (7%) | catalogued as rs1437820985, COSV101184456; called by muse, mutect2
- ARF6 | c.*228G>T | 3'UTR (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100028319; called by muse, mutect2, varscan2
- ARHGAP26 | c.1538+168A>T | Intron (SNP) | VAF 50/177 reads (28%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.2225+30A>T | Intron (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- ASB10 | chr7:151187644 A>T | 5'Flank (SNP) | VAF 4/73 reads (5%) | catalogued as COSV99317987; called by muse, mutect2
- CNN1 | c.-3A>T | 5'UTR (SNP) | VAF 14/155 reads (9%) | catalogued as COSV99372153; called by muse, mutect2
- CREBZF | c.*251A>T | 3'UTR (SNP) | VAF 10/145 reads (7%) | called by muse, mutect2
- HUWE1 | c.8206+1155A>T | Intron (SNP) | VAF 54/714 reads (8%) | catalogued as COSV99469977; called by muse, mutect2
- IFNAR2 | c.-84+313A>T | Intron (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- IVL | c.*204T>A | 3'UTR (SNP) | VAF 65/148 reads (44%) | catalogued as COSV100908065; called by muse, varscan2
- KCNF1 | c.*110C>A | 3'UTR (SNP) | VAF 41/140 reads (29%) | catalogued as COSV99705429; called by muse, mutect2, varscan2
- KCNF1 | c.*111C>A | 3'UTR (SNP) | VAF 41/137 reads (30%) | catalogued as COSV99705430; called by muse, mutect2, varscan2
- MAP10 | c.*222A>T | 3'UTR (SNP) | VAF 6/76 reads (8%) | catalogued as COSV101406408; called by muse, mutect2
- MIR200A | n.31T>A | RNA (SNP) | VAF 24/298 reads (8%) | called by muse, mutect2
- RAB42 | c.*1299T>A | 3'UTR (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- SEMA6D | c.1647-38C>A | Intron (SNP) | VAF 78/183 reads (43%) | catalogued as COSV60381648; called by muse, mutect2, varscan2
- SNURFL | n.200A>T | RNA (SNP) | VAF 46/526 reads (9%) | called by muse, mutect2
- TENM4 | c.-321+38417T>C | Intron (SNP) | VAF 53/145 reads (37%) | catalogued as COSV53654748; called by muse, mutect2, varscan2
